Gene-level copy-number profile of tumor specimen TCGA-61-1727-01A from TCGA case TCGA-61-1727, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 74.5 years (27,203 days).
Specimen TCGA-61-1727-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.1945210f-1564-43d1-9590-2ff9f0700e82.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1727-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c4fda99e-6a9a-4a05-8637-f9b9c3f7bd05

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,322; copy number 2: 22,280; copy number 3: 22,719; copy number 4: 7,016; copy number 5: 2,526; copy number 6: 563; copy number 7: 619; copy number 8: 210; copy number 9: 296; copy number 10: 190; copy number 11: 68.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-1727-01A-01D-0577-01): tumor purity 0.56, ploidy 2.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,063 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,402,721–36,775,768, 9 genes, copy number 5: RNU4-27P, OSCP1, SNORA63C, MRPS15, CSF3R, FTLP18, AL596257.1, AC117945.2, AC117945.1.
- chr1:38,708,931–40,072,649, 48 genes, copy number 5 (within-gene range 4–5): HSPA5P1, AL354702.1, RRAGC, AL139260.2, AL139260.1, MYCBP, AL139260.3, GJA9, RHBDL2, RNU6-605P, Y_RNA, EIF1P2, AKIRIN1, NDUFS5, MACF1, RNU6-608P, RNA5SP44, AL442071.2, AL442071.1, HSPE1P8, BMP8A, OXCT2P1, PPIEL, PABPC4, PABPC4-AS1, SNORA55, HEYL, AL035404.2, NT5C1A, HPCAL4, PPIE, AL035404.1, RNU7-121P, BMP8B, OXCT2, BMP8B-AS1, AL033527.2, AL033527.1, AL033527.3, LINC02811, TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1.
- chr1:46,489,836–48,497,736, 58 genes, copy number 5: DMBX1, TMEM275, MKNK1-AS1, KNCN, MKNK1, MOB3C, ATPAF1, NENFP1, TEX38, EFCAB14-AS1, EFCAB14, AL593856.1, CYP4B1, CYP4Z2P, TUBAP8, CYP4A11, CYP4A26P, CYP4A43P, CYP4A27P, CYP4A44P, CYP4X1, CYP4Z1, TUBAP9, CYP4A22-AS1, CYP4A22, MTND1P34, LINC00853, PDZK1IP1, TAL1, AL135960.1, STIL, CMPK1, LINC01389, FOXE3, FOXD2-AS1, FOXD2, AL356458.1, RPL21P24, ATP6V0E1P4, LINC01738, TRABD2B, AL691459.1, AC096541.1, LINC02794, AL356289.1, CYP46A4P, SKINT1L, AL356289.2, AL109659.1, SLC5A9, AL109659.2, AL109659.3, SPATA6, PPP1R8P1, RNU6-723P, AL356968.2, RNU4-61P, AL356968.1.
- chr1:48,552,991–48,776,969, 2 genes, copy number 5: AL391844.1, BEND5.
- chr1:224,896,262–231,118,325, 190 genes, copy number 5 (broad region; genes not listed).
- chr2:214,241,676–216,664,436, 47 genes, copy number 5 (within-gene range 3–5): AC068051.1, RPL5P8, VWC2L, VWC2L-IT1, ENSAP3, BARD1, SNHG31, SNORA70I, RPL10P6, ABCA12, AC072062.1, AC092844.1, LINC02862, ATIC, FN1, AC012462.3, AC012462.1, AC012462.2, AC012668.2, AC012668.3, AC012668.1, LINC00607, LINC01614, AC093850.1, AC122136.1, AC093382.1, MREG, PECR, TMEM169, XRCC5, POLHP1, AC012513.2, AC012513.3, LINC01963, MARCHF4, AC012513.1, AC069155.1, Y_RNA, SMARCAL1-AS1, SMARCAL1, RPL37A-DT, AC098820.1, RPL37A, LINC01280, AC073321.1, PSMB3P2, IGFBP2.
- chr6:68,332,019–71,652,611, 44 genes, copy number 5 (within-gene range 3–5): AL606923.2, AL606923.1, AL391807.1, ADGRB3, LMBRD1, NPM1P37, GAPDHP42, COL19A1, RPL37P15, COL9A1, AL160262.1, AL080275.1, AL365226.1, FAM135A-AS1, FAM135A, RNU7-48P, SDHAF4, AL583856.2, AL583856.1, SLC25A6P6, SMAP1, AL354943.1, NDUFAB1P1, B3GAT2, AL096709.1, BECN1P2, U3, LYPLA1P3, RNU6-411P, AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626, AL035467.2, AL035467.1, KRT19P1, RNU4-66P.
- chr6:117,907,264–118,783,420, 9 genes, copy number 5: SLC35F1, AL450405.1, AL589993.1, CEP85L, BRD7P3, PLN, Z99496.1, SSXP10, SELENOKP3.
- chr7:82,589,848–83,162,930, 4 genes, copy number 5 (within-gene range 3–5): MTHFD2P5, AC004006.1, PCLO, RNA5SP235.
- chr8:48,384,590–84,921,844, 525 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:124,550,784–145,066,685, 379 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr10:28,743,506–37,602,974, 148 genes, copy number 6 (broad region; genes not listed).
- chr10:69,161,530–81,875,133, 295 genes, copy number 5–9 (broad region; genes not listed).
- chr11:31,280,672–45,772,358, 208 genes, copy number 8–11 (broad region; genes not listed).
- chr15:71,547,280–101,933,350, 817 genes, copy number 5–8 (broad region; genes not listed).
- chr16:16,952,502–23,596,316, 189 genes, copy number 10 (broad region; genes not listed).
- chr16:23,605,841–23,624,107, 1 gene, copy number 10 (within-gene range 3–10): AC008870.4.
- chr18:48,026,672–53,629,990, 92 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:4,686,350–10,673,999, 99 genes, copy number 5 (broad region; genes not listed).
- chr20:47,209,214–64,313,132, 412 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr22:25,102,433–35,347,992, 298 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr22:36,560,857–36,703,752, 1 gene, copy number 5 (within-gene range 4–5): CACNG2.
- chr22:36,703,918–41,240,931, 188 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,292. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
